CPTAC case C3L-00093 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1a180fc6-b37a-47de-862f-1991f3096536

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1949; Vital status: Dead; Days to death: 1,703 days (4.7 years); Year of death: 2021; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 66.5 years (24,301 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,703 days (4.7 years); Progression or recurrence: yes; Days to last follow up: 1,698 days (4.6 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm (a second GDC size field records 4.7 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 10; Margin status: Uninvolved.

Follow-up (5 entries)
- Days to follow up: 385 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 1,437 days (3.9 years); Disease response: With Tumor.
- Days to follow up: 1,698 days (4.6 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 1,176 days (3.2 years).
- Days to follow up: 1,698 days (4.6 years); Disease response: With Tumor.
- Follow-up contacts recording only the day: day 763, day 1,058.

Other clinical attributes
- Weight: 84 kg; Height: 157 cm; BMI: 34.08; FEV1/FVC after bronchodilator (%): 74; FEV1/FVC before bronchodilator (%): 69; FEV1 before bronchodilator (% of reference): 97.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00093-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 234 mg; Time between excision and freezing: 40 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00093-21: Section location: Left Lower Lobe; Percent tumor nuclei: 65; Percent necrosis: 2.
- Sample C3L-00093-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 309 mg; Time between excision and freezing: 40 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00093-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
